Gene-level copy-number profile of tumor specimen TCGA-95-A4VK-01A from TCGA case TCGA-95-A4VK, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.0 years (27,040 days).
Specimen TCGA-95-A4VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.aa153556-d066-45cb-a8bb-16ea9d217a0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-A4VK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32a3e2c5-814d-42fd-bd25-f70e9fa3038f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 68; copy number 2: 8,930; copy number 3: 398; copy number 4: 42,676; copy number 5: 58; copy number 6: 7,215; copy number 7: 43; copy number 8: 216; copy number 9: 17; copy number 10: 107; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-A4VK-01A-11D-A25M-01): tumor purity 0.57, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.
- chr9:19,895,800–23,898,054, 83 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 126 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:153,755,382–154,461,053, 12 genes, copy number 9: RN7SL177P, LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L.
- chr5:162,477,891–162,762,313, 2 genes, copy number 9: RNU6-164P, ARL2BPP5.
- chr5:165,129,307–166,382,599, 9 genes, copy number 10: AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr5:167,653,228–167,729,124, 2 genes, copy number 11: AC008708.2, AC008708.1.
- chr5:168,993,000–169,037,998, 3 genes, copy number 9: AC011389.1, AC011389.2, SLIT3-AS1.
- chr5:179,110,853–181,342,213, 98 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
